Somatic mutation profile of tumor specimen 0DLDZO from CCDI case PBBYYH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 1.9 years (685 days).
Specimen 0DLDZO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60793c00-afd9-48be-aa7d-4760a51d7ad7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLDZ9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b69505e-d9ae-4a97-af7c-32ff615f138f

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP23 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 13/348 reads (4%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.72); catalogued as rs1405163893; called by muse, mutect2
- BRSK2 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 183/205 reads (89%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1387401134, COSV57540934; called by muse, mutect2, varscan2
- CEACAM5 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 317/688 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782212178, COSV55753558; called by muse, mutect2, varscan2
- PDK2 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 143/971 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs527571228; called by muse, mutect2, varscan2
- PHACTR4 | c.151A>G p.K51E (on ENST00000373839 / NM_001350159.2; = p.K61E on NM_023923.4) | Missense Mutation (SNP) | VAF 305/636 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs550399400, COSV65783432; called by mutect2, varscan2
- SH3PXD2B | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 219/464 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs757510919; called by muse, mutect2, varscan2
- SLC25A12 | c.1088T>A p.V363D | Missense Mutation (SNP) | VAF 193/488 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV55536532; called by muse, mutect2, varscan2
- MARCHF10 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 278/505 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PASD1 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MAP3K6 | c.237C>T p.C79= | Silent (SNP) | VAF 253/499 reads (51%) | called by muse, mutect2, varscan2
- WBP11 | c.756C>T p.T252= | Silent (SNP) | VAF 11/396 reads (3%) | called by muse, mutect2
- ANKRD6 | c.792+59C>A | Intron (SNP) | VAF 13/337 reads (4%) | called by muse, mutect2
